Somatic mutation profile of tumor specimen BA2664D (aliquot aq-BA2664D) from BEATAML1.0 case 2565, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Primary diagnosis: Myelodysplastic syndrome, unclassifiable; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.9 years (23,354 days).
Specimen BA2664D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a05e8594-b7e9-4dbe-9c52-8010226d23a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2064D (Solid Tissue Normal), aliquot aq-BA2064D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae1e99d9-f134-42b5-8a43-9d9f7b672997

The open-access MAF lists 20 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, Intron 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 136/316 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876658468, COSV52675896, COSV52688299, COSV52757395; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HECTD3 | c.179G>T p.R60L | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV99870317; called by muse, mutect2
- LILRB3 | c.1286C>A p.P429Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.09); catalogued as rs955914127; called by muse, mutect2, varscan2
- PTPRJ | c.3980C>G p.T1327S | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV69250277; called by mutect2, varscan2
- SELL | c.212G>A p.R71Q (on ENST00000650983; = p.R58Q on NM_000655.5) | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770641838; called by muse, mutect2, varscan2
- ARNT2 | c.408G>T p.Q136H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- CNGB3 | c.689A>C p.N230T | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2
- DDX54 | c.2086A>G p.S696G | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ITGB5 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- KCNAB3 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.108); called by muse, mutect2
- LILRB3 | c.1285C>A p.P429T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MED12 | c.2491G>T p.A831S | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT tolerated (0.83); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPP2R2B | c.984G>T p.K328N (on ENST00000394409; = p.K394N on NM_181674.2) | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- ANAPC2 | c.108G>C p.A36= | Silent (SNP) | VAF 24/134 reads (18%) | called by muse, mutect2, varscan2
- PPP4R3C | c.147G>T p.S49= | Silent (SNP) | VAF 24/142 reads (17%) | called by muse, mutect2, varscan2
- RBP3 | c.2586G>T p.L862= | Silent (SNP) | VAF 33/152 reads (22%) | called by muse, mutect2, varscan2
- WDR19 | c.285C>T p.G95= | Silent (SNP) | VAF 6/75 reads (8%) | catalogued as rs1192452218; called by muse, mutect2
- CASP8 | c.306-1919A>G | Intron (SNP) | VAF 34/199 reads (17%) | called by muse, mutect2, varscan2
- CDK18 | c.1311+36G>C | Intron (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2
- IP6K3 | c.-6G>A | 5'UTR (SNP) | VAF 20/76 reads (26%) | called by muse, mutect2, varscan2
